Somatic mutation profile of tumor specimen TCGA-D5-6535-01A (aliquot TCGA-D5-6535-01A-11D-1719-10) from TCGA case TCGA-D5-6535, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 80.2 years (29,278 days).
Specimen TCGA-D5-6535-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa938417-5c1b-4c98-b557-6d6df39e42bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6535-10A (Blood Derived Normal), aliquot TCGA-D5-6535-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffe712b7-8eb1-4d6c-bb69-7bb86eef3a5f

The open-access MAF lists 180 somatic variants for this specimen: 139 protein-altering or splice-affecting, 39 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 39, Nonsense Mutation 9, Splice Site 3, In Frame Del 2, Intron 2, Splice Region 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 53/101 reads (52%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 77/103 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 48/84 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.277G>T p.V93F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV66060138; called by muse, mutect2, varscan2
- ABCA13 | c.6793G>T p.E2265* | Nonsense Mutation (SNP) | VAF 74/393 reads (19%) | catalogued as COSV101330198; called by muse, mutect2, varscan2
- ABCC9 | c.2123G>C p.G708A | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53987976, COSV99685282; called by muse, mutect2, varscan2
- ACSS2 | c.1613C>G p.T538R | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99490277; called by muse, mutect2, varscan2
- ACTG1 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs782638106, COSV59510117; called by muse, mutect2, varscan2
- ADGRV1 | c.6495A>C p.E2165D | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101316642; called by muse, mutect2, varscan2
- AK3 | c.88C>G p.H30D | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV63347355; called by muse, mutect2, varscan2
- AKT3 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs772090769, COSV55634532; called by muse, mutect2, varscan2
- AMER2 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV63440575; called by muse, mutect2, varscan2
- APOL2 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV50773354; called by muse, mutect2, varscan2
- ARHGAP30 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs200926712; called by muse, mutect2, varscan2
- ARHGAP33 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.593); catalogued as rs959723516, COSV50176178; called by muse, mutect2, varscan2
- ARL13B | c.1187C>G p.P396R (on ENST00000394222 / NM_001174150.2; = p.P289R on NM_144996.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV57402232; called by muse, mutect2
- ARL9 | c.622C>T p.L208F (on ENST00000640821 / NM_001363794.2; = p.L66F on NM_206919.2) | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs779105544, COSV63991595; called by muse, mutect2, varscan2
- AVPR1A | c.969C>T p.T323= | Splice Region (SNP) | VAF 22/133 reads (17%) | catalogued as rs377304458, COSV100146887; called by muse, mutect2, varscan2
- B3GNT2 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1244387179, COSV57345987; called by muse, mutect2, varscan2
- BRI3 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99805629; called by muse, mutect2, varscan2
- C6orf118 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 67/105 reads (64%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.887); catalogued as rs201539458, COSV57815326; called by muse, mutect2, varscan2
- C7orf61 | c.51G>C p.R17S | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV100190210, COSV55725551; called by muse, mutect2, varscan2
- CARNMT1 | c.644C>A p.A215D | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100961820, COSV65193109; called by muse, mutect2, varscan2
- CCDC96 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV59508720, COSV59509743; called by muse, varscan2
- CD109 | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749134372, COSV54646604; called by muse, mutect2, varscan2
- CEP128 | c.3235A>G p.T1079A | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55392174; called by muse, mutect2, varscan2
- CEP70 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 218/585 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV53878754; called by muse, mutect2, varscan2
- CES5A | c.1446G>T p.K482N (on ENST00000290567 / NM_001143685.2; = p.K432N on NM_145024.3) | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); catalogued as COSV51871284; called by muse, mutect2, varscan2
- CLSTN1 | c.2560G>A p.A854T (on ENST00000377298 / NM_001009566.3; = p.A844T on NM_014944.4) | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs754287069, COSV63132161; called by muse, mutect2, varscan2
- COG8 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs375728590; called by muse, varscan2
- COL15A1 | c.1315T>A p.S439T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); catalogued as COSV66649872; called by muse, mutect2, varscan2
- CREB3 | c.697-1G>A p.X233_splice | Splice Site (SNP) | VAF 86/341 reads (25%) | catalogued as COSV59212213; called by muse, mutect2, varscan2
- CSDE1 | c.1560_1565del p.L520_Y522delinsF (on ENST00000358528 / NM_001007553.3; = p.L489_Y491delinsF on NM_007158.6) | In Frame Del (DEL) | VAF 18/67 reads (27%) | catalogued as COSV54762056; called by mutect2, pindel*, varscan2*
- CSMD3 | c.207A>C p.L69F | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV99849927; called by muse, mutect2, varscan2
- CTR9 | c.3044C>A p.S1015* | Nonsense Mutation (SNP) | VAF 14/123 reads (11%) | catalogued as COSV100797544, COSV63729844; called by muse, mutect2
- DIRAS1 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1466739657, COSV60216831; called by muse, mutect2, varscan2
- DNAH10 | c.4231G>T p.E1411* (on ENST00000409039; = p.E1350* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 38/114 reads (33%) | catalogued as COSV69003401; called by muse, mutect2, varscan2
- DNAH11 | c.6895G>C p.E2299Q | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181205; called by muse, mutect2, varscan2
- DSCAML1 | c.472G>A p.D158N (on ENST00000321322; = p.D98N on NM_020693.4) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as rs1276241297, COSV58396974; called by muse, mutect2, varscan2
- DVL3 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53049043; called by muse, mutect2, varscan2
- EHBP1 | c.3592G>T p.A1198S | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV50441469; called by muse, mutect2, varscan2
- ERN2 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 211/534 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56838366; called by muse, mutect2, varscan2
- FAM124A | c.122C>T p.A41V (on ENST00000322475 / NM_001242312.2; = p.A77V on NM_145019.4) | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1237073980, COSV54479844; called by muse, mutect2, varscan2
- FHL5 | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV58736761, COSV58740988; called by muse, mutect2, varscan2
- FKRP | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.797); catalogued as rs140217866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC3A | c.418G>A p.V140M (on ENST00000492622 / NM_001079673.2; = p.V84M on NM_014923.5) | Missense Mutation (SNP) | VAF 82/247 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs199834112, COSV101001373; called by muse, mutect2, varscan2
- FOXO1 | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65429038; called by muse, mutect2, varscan2
- FOXRED1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV55007156; called by muse, mutect2, varscan2
- FREM2 | c.5411G>A p.S1804N | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV54839893; called by muse, mutect2, varscan2
- GGT5 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs759124656, COSV54068737; called by muse, mutect2, varscan2
- GNG4 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs756924811, COSV64000170; called by muse, mutect2, varscan2
- GOLGB1 | c.5125A>C p.T1709P | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV100511602; called by muse, mutect2, varscan2
- GPC5 | c.1280+2T>A p.X427_splice | Splice Site (SNP) | VAF 35/121 reads (29%) | catalogued as COSV100996245; called by muse, mutect2, varscan2
- HIGD2A | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.497); catalogued as COSV99220973; called by muse, mutect2, varscan2
- HRH2 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 135/505 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51576605; called by muse, mutect2, varscan2
- HSPB2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 77/411 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV99909988; called by muse, mutect2, varscan2
- HTR2C | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV52208379, COSV52225992; called by muse, mutect2, varscan2
- IGF1 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61034767; called by muse, mutect2
- IQSEC2 | c.3229C>T p.R1077C (on ENST00000642864 / NM_001111125.3; = p.R872C on NM_015075.2) | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs782569979, COSV64728374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGAM | c.1672G>A p.G558R (on ENST00000648685 / NM_001145808.2; = p.G557R on NM_000632.4) | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199951990; called by muse, mutect2, varscan2
- KBTBD6 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.834); catalogued as COSV65272070; called by muse, mutect2, varscan2
- KCNH5 | c.1855A>G p.K619E | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100528383; called by muse, varscan2
- KCNH7 | c.201C>A p.D67E | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.727); catalogued as COSV59815333; called by muse, mutect2, varscan2
- KCNU1 | c.2513C>T p.S838L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.11); catalogued as COSV67760195; called by muse, mutect2, varscan2
- KDM7A | c.1903C>G p.Q635E | Missense Mutation (SNP) | VAF 81/425 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV50097437; called by muse, mutect2, varscan2
- KIF13B | c.4066T>A p.L1356I | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV101576076; called by muse, mutect2, varscan2
- LDB2 | c.790A>T p.T264S | Missense Mutation (SNP) | VAF 160/762 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV58784268; called by muse, mutect2, varscan2
- LEXM | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs747586144, COSV64023909; called by muse, mutect2, varscan2
- LGALS13 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55681001; called by muse, mutect2, varscan2
- LGALS3BP | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771490373, COSV99431975; called by muse, mutect2, varscan2
- LILRA2 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 76/416 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52191124; called by muse, mutect2
- LMTK2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs772440680, COSV52005120; called by muse, mutect2, varscan2
- LRCH1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 113/322 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV60854032; called by muse, mutect2, varscan2
- LRFN1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.066); catalogued as COSV50498173; called by muse, mutect2, varscan2
- MAML1 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 41/157 reads (26%) | catalogued as COSV52989114; called by muse, mutect2, varscan2
- MAP2K4 | c.239G>A p.S80N | Missense Mutation (SNP) | VAF 110/183 reads (60%) | SIFT tolerated (0.36); PolyPhen benign (0.306); catalogued as COSV62261228; called by muse, mutect2, varscan2
- MAP6 | c.2417C>T p.T806M | Missense Mutation (SNP) | VAF 107/219 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as rs573813818, COSV59077004; called by muse, mutect2, varscan2
- MIP | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs966166555, COSV57509765; called by muse, mutect2, varscan2
- MYH13 | c.856C>A p.H286N | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52834243, COSV52844451; called by muse, mutect2, varscan2
- MYO3A | c.3023C>T p.S1008L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as rs752039263, COSV56328707; called by muse, mutect2, varscan2
- NACA | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 172/406 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV63273453; called by muse, mutect2, varscan2
- NCAM1 | c.1795G>T p.A599S (on ENST00000316851 / NM_181351.5; = p.A589S on NM_000615.7) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV57510769, COSV57525977; called by muse, mutect2, varscan2
- NCAPG | c.1362T>G p.D454E | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99266229; called by muse, mutect2, varscan2
- NCAPG | c.2964G>T p.M988I | Missense Mutation (SNP) | VAF 162/362 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV52273035; called by muse, mutect2, varscan2
- NSMAF | c.1842G>A p.W614* | Nonsense Mutation (SNP) | VAF 210/522 reads (40%) | catalogued as COSV50702516; called by muse, mutect2, varscan2
- NTNG2 | c.482G>A p.W161* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as COSV62369100; called by muse, mutect2, varscan2
- OR1A2 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV101126367, COSV67936872; called by muse, mutect2, varscan2
- OR4A5 | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV100157333; called by muse, mutect2
- OR51B5 | c.179T>A p.F60Y | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs529250070, COSV56177466; called by muse, mutect2, varscan2
- OS9 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1254843771, COSV57783963; called by muse, mutect2, varscan2
- OSBPL10 | c.1878C>A p.F626L | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs757945528, COSV67344664; called by muse, mutect2, varscan2
- PIP | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV52121825; called by muse, mutect2, varscan2
- PKHD1L1 | c.8762A>C p.E2921A | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV65754637; called by muse, mutect2, varscan2
- PLAAT1 | c.346T>C p.Y116H (on ENST00000650797; = p.Y11H on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV53234230; called by muse, mutect2, varscan2
- PLCB1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1423560967, COSV62045086; called by muse, mutect2, varscan2
- PMS1 | c.1910G>C p.R637T | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV59720573; called by muse, mutect2, varscan2
- PRICKLE1 | c.591A>C p.I197= | Splice Region (SNP) | VAF 7/67 reads (10%) | catalogued as COSV61547274; called by muse, mutect2, varscan2
- PXDNL | c.4357C>T p.R1453* | Nonsense Mutation (SNP) | VAF 24/169 reads (14%) | catalogued as rs753425862, COSV62499622; called by muse, mutect2, varscan2
- RBM46 | c.1448G>A p.S483N | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55982273; called by muse, mutect2, varscan2
- RELA | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV58016230; called by muse, mutect2, varscan2
- RHCE | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.331); catalogued as COSV53803734; called by muse, mutect2, varscan2
- RIMS2 | c.2561C>T p.T854M (on ENST00000666250 / NM_001348490.2; = p.T662M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749970132, COSV51665339; called by muse, mutect2, varscan2
- RNF19A | c.1728T>G p.S576R | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100348190; called by muse, mutect2, varscan2
- SEC14L1 | c.986G>C p.G329A | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66725796; called by muse, mutect2, varscan2
- SEC24D | c.2945C>A p.P982Q | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.09); catalogued as COSV54885470; called by muse, mutect2, varscan2
- SEMA6C | c.826C>A p.H276N | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV59008219; called by muse, mutect2, varscan2
- SLC17A7 | c.1289C>A p.A430D | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55550387; called by muse, mutect2, varscan2
- SLC39A8 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63224455; called by muse, mutect2, varscan2
- SLC4A8 | c.2780G>A p.R927H | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs894076715, COSV100177007; called by muse, mutect2, varscan2
- SLIT3 | c.631C>A p.R211S | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779134549, COSV100270387; called by muse, mutect2, varscan2
- SLITRK5 | c.2007C>A p.S669R | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV61526819; called by muse, mutect2, varscan2
- SPANXN2 | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 191/322 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65129632; called by muse, mutect2, varscan2
- SRCAP | c.7213G>C p.E2405Q | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV52682000; called by muse, mutect2, varscan2
- SRGAP3 | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201685879; called by muse, mutect2, varscan2
- SRPK2 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs765069789, COSV61959711, COSV61961138; called by muse, mutect2, varscan2
- SVEP1 | c.4828G>A p.D1610N | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65690343; called by muse, mutect2, varscan2
- TBX5 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs377532269; ClinVar: benign; called by muse, mutect2, varscan2
- TDRD3 | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.391); catalogued as rs766180388, COSV52164824; called by muse, mutect2, varscan2
- TFAM | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV65877360; called by muse, mutect2, varscan2
- TMEM131 | c.5366C>T p.T1789I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV51787308; called by muse, mutect2, varscan2
- TRPS1 | c.2923G>A p.V975I (on ENST00000220888 / NM_001330599.2; = p.V988I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/558 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs764941297, COSV55264497; called by muse, mutect2, varscan2
- TTN | c.83567C>A p.S27856Y (on ENST00000591111; = p.S20432Y on NM_003319.4) | Missense Mutation (SNP) | VAF 46/174 reads (26%) | PolyPhen possibly damaging (0.837); catalogued as COSV100633283; called by muse, mutect2, varscan2
- UNC13A | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53193381; called by muse, mutect2, varscan2
- USP29 | c.1841G>T p.S614I | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV54147112; called by muse, mutect2, varscan2
- UTP20 | c.5596C>T p.R1866C | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs778767258, COSV55379110; called by muse, mutect2
- VPS37D | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs781963354, COSV61447317; called by mutect2, varscan2
- WDFY3 | c.1872G>C p.K624N | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55715107; called by muse, mutect2, varscan2
- ZBTB41 | c.2708C>A p.S903Y | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as COSV100963491; called by muse, mutect2, varscan2
- ZFP28 | c.521C>A p.P174Q | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV56738400; called by muse, mutect2, varscan2
- ZIC5 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57438496, COSV57439137; called by muse, mutect2, varscan2
- ZNF257 | c.473C>A p.S158* | Nonsense Mutation (SNP) | VAF 56/147 reads (38%) | catalogued as COSV101448176, COSV71306330; called by muse, mutect2, varscan2
- ZNF418 | c.1778G>T p.C593F | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68675841, COSV68676269; called by muse, mutect2, varscan2
- ZNF45 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV99524286; called by muse, mutect2, varscan2
- ZNF713 | c.426T>A p.F142L (on ENST00000633730 / NM_001366796.2; = p.F155L on NM_182633.3) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV70057264; called by muse, mutect2, varscan2
- ZNF829 | c.1087C>A p.Q363K | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV66987069; called by muse, mutect2, varscan2
- AL645922.1 | c.973dup p.T325Nfs*8 | Frame Shift Ins (INS) | VAF 106/187 reads (57%) | called by mutect2, pindel, varscan2
- GDA | c.822+3_822+6del p.X274_splice | Splice Site (DEL) | VAF 41/83 reads (49%) | called by mutect2, pindel, varscan2
- HERC4 | c.159_173del p.T54_C58del | In Frame Del (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel
- MRC1 | c.2106A>C p.L702F | Missense Mutation (SNP) | VAF 108/437 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ANK1 | c.579G>T p.L193= | Silent (SNP) | VAF 38/56 reads (68%) | catalogued as COSV55897477; called by muse, mutect2, varscan2
- ANXA11 | c.897C>T p.L299= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as rs773985331, COSV55416971; called by muse, mutect2, varscan2
- ARHGEF4 | c.1723C>T p.L575= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV58131022; called by muse, mutect2, varscan2
- C19orf57 | c.711A>C p.L237= | Silent (SNP) | VAF 74/208 reads (36%) | catalogued as COSV60970548; called by muse, mutect2, varscan2
- C1GALT1 | c.546T>C p.L182= | Silent (SNP) | VAF 85/226 reads (38%) | catalogued as COSV56180671; called by muse, mutect2, varscan2
- CCDC120 | c.1260C>T p.A420= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs374295188, COSV64481859; called by muse, mutect2, varscan2
- CDK15 | c.1164C>T p.S388= (on ENST00000652192 / NM_001366386.2; = p.S337= on NM_139158.2) | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as rs750408097, COSV53639151; called by muse, mutect2, varscan2
- CEP170 | c.3280A>C p.R1094= | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as COSV60515604; called by muse, mutect2, varscan2
- DACH1 | c.753G>A p.L251= | Silent (SNP) | VAF 42/216 reads (19%) | catalogued as COSV57516111; called by muse, mutect2, varscan2
- DAGLA | c.2880C>T p.L960= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV57200498; called by muse, mutect2, varscan2
- DCBLD1 | c.1188C>A p.P396= | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as COSV99758220; called by muse, mutect2, varscan2
- DDX11 | c.816G>A p.V272= | Silent (SNP) | VAF 94/522 reads (18%) | catalogued as COSV52511939; called by muse, mutect2, varscan2
- EME1 | c.1377C>T p.F459= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as COSV56815706; called by muse, mutect2, varscan2
- ENOX2 | c.360C>A p.T120= (on ENST00000338144 / NM_001382520.1; = p.T91= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as COSV57658640; called by muse, mutect2, varscan2
- FERMT3 | c.1930C>A p.R644= (on ENST00000279227 / NM_178443.3; = p.R640= on NM_031471.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV54174076, COSV54176018; called by muse, mutect2, varscan2
- FMN2 | c.3342C>T p.P1114= | Silent (SNP) | VAF 52/378 reads (14%) | catalogued as rs753146847, COSV60453976; called by muse, mutect2, varscan2
- GALR3 | c.330C>T p.S110= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs372084041; called by muse, mutect2, varscan2
- H2BC9 | c.111C>T p.S37= | Silent (SNP) | VAF 53/231 reads (23%) | catalogued as COSV99769299; called by muse, mutect2, varscan2
- KCNH4 | c.1722C>G p.T574= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs759619099, COSV52921456; called by muse, mutect2, varscan2
- MOCS2 | c.162T>C p.L54= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV63741522; called by muse, mutect2, varscan2
- MRPS33 | c.102G>A p.V34= | Silent (SNP) | VAF 54/286 reads (19%) | catalogued as COSV100244769; called by muse, varscan2
- MTMR1 | c.1455G>T p.V485= | Silent (SNP) | VAF 25/184 reads (14%) | catalogued as COSV64893055; called by muse, mutect2, varscan2
- MYCN | c.846G>A p.V282= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV55257789; called by muse, mutect2, varscan2
- NOS1 | c.1803C>T p.R601= | Silent (SNP) | VAF 86/136 reads (63%) | catalogued as rs371959195; called by muse, mutect2, varscan2
- NYNRIN | c.3495C>T p.T1165= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs369620295; called by muse, mutect2
- POM121C | c.3105C>G p.A1035= (on ENST00000607367; = p.A793= on NM_001099415.3) | Silent (SNP) | VAF 40/221 reads (18%) | catalogued as COSV57549783; called by muse, varscan2
- PTX3 | c.264G>A p.L88= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1295080372, COSV99905032; called by muse, mutect2
- RIMS1 | c.2049T>A p.P683= | Silent (SNP) | VAF 66/187 reads (35%) | catalogued as COSV53487668; called by muse, mutect2, varscan2
- SCN1A | c.1986G>A p.S662= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as COSV57689905; called by muse, mutect2, varscan2
- SEC61A1 | c.639C>A p.I213= | Silent (SNP) | VAF 55/293 reads (19%) | catalogued as COSV54579262; called by muse, mutect2, varscan2
- SPSB3 | c.144C>T p.S48= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs779190396, COSV51908782; called by muse, mutect2, varscan2
- STK33 | c.1515C>T p.G505= | Silent (SNP) | VAF 119/655 reads (18%) | catalogued as rs752970888, COSV59403477; called by muse, mutect2, varscan2
- TBX1 | c.672C>T p.D224= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs367657296, COSV60353140; called by muse, mutect2, varscan2
- TRPM3 | c.2073C>T p.D691= (on ENST00000357533 / NM_001366142.2; = p.D534= on NM_020952.6) | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs530661575, COSV62596033; called by muse, mutect2, varscan2
- USP16 | c.993T>G p.T331= | Silent (SNP) | VAF 41/156 reads (26%) | catalogued as COSV57628201; called by muse, mutect2, varscan2
- VPS13B | c.6288A>C p.P2096= | Silent (SNP) | VAF 38/202 reads (19%) | catalogued as COSV62158856; called by muse, mutect2, varscan2
- WFIKKN2 | c.789C>T p.N263= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs772880320, COSV60959127; called by muse, mutect2, varscan2
- ZNF415 | c.1353G>A p.V451= | Silent (SNP) | VAF 48/202 reads (24%) | catalogued as COSV99702112; called by muse, mutect2, varscan2
- ZNF551 | c.348T>C p.I116= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as COSV56595395; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7442T>C | Intron (SNP) | VAF 26/64 reads (41%) | catalogued as COSV63394806; called by muse, mutect2, varscan2
- PCDHA9 | c.2394+134A>G | Intron (SNP) | VAF 45/253 reads (18%) | catalogued as COSV65333469; called by muse, mutect2, varscan2
